Somatic mutation profile of tumor specimen BA2798D (aliquot aq-BA2798D) from BEATAML1.0 case 2395, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.3 years (26,054 days).
Specimen BA2798D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a7843b0-f481-47f3-ae61-510013b6da91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2943D (Solid Tissue Normal), aliquot aq-BA2943D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a504a20-a5a4-4b30-9f90-ea5be0355ab4

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 5'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 49/126 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO16 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51786860; called by muse, mutect2, varscan2
- SMIM32 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1202411627; called by muse, mutect2
- SPG11 | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 134/324 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs373796566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TET2 | c.4096C>A p.R1366S | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104371869; called by muse, mutect2, varscan2
- BMP3 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CNTNAP1 | c.1667A>G p.Y556C | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.525); called by muse, varscan2
- COL6A6 | c.2374G>C p.V792L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2
- EZH2 | c.1396-3C>G | Splice Region (SNP) | VAF 69/88 reads (78%) | called by muse, mutect2, varscan2
- RBMS1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, varscan2
- RUNX1 | c.1138_1141dup p.G381Vfs*193 (on ENST00000344691 / NM_001001890.3; = p.G408Vfs*193 on NM_001754.5) | Frame Shift Ins (INS) | VAF 26/65 reads (40%) | called by mutect2, pindel, varscan2
- ANKRD6 | c.231C>A p.T77= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- C1orf127 | c.2121G>T p.L707= | Silent (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- PILRA | c.309G>A p.E103= | Silent (SNP) | VAF 108/255 reads (42%) | catalogued as COSV52200164; called by muse, mutect2, varscan2
- TNRC6C | c.4467C>A p.A1489= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- RCOR3 | chr1:211259701 C>A | 5'Flank (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
